Somatic mutation profile of tumor specimen TARGET-10-PATSDS-03A (aliquot TARGET-10-PATSDS-03A-01D) from TARGET case TARGET-10-PATSDS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,428 days).
Specimen TARGET-10-PATSDS-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a58a4e24-1da6-4e4a-8dc7-28a961650eb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATSDS-10A (Blood Derived Normal), aliquot TARGET-10-PATSDS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8be0c30f-14bc-40b2-9c1a-121b13ee11fd

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs760195858, COSV58466344; called by muse, mutect2, varscan2
- APPBP2 | c.242A>G p.H81R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.599); catalogued as COSV50031116; called by muse, mutect2, varscan2
- C11orf80 | c.658A>G p.N220D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV60931867; called by muse, mutect2, varscan2
- CNTN1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191888454, COSV61636657; called by muse, mutect2, varscan2
- CNTNAP5 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs760438818, COSV70470252; called by muse, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, varscan2
- PCDHA5 | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV65354574, COSV65358647; called by muse, mutect2, varscan2
- RP1 | c.5502G>T p.L1834F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV55130049; called by muse, mutect2, varscan2
- SLC2A10 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.69); PolyPhen benign (0.082); catalogued as rs201268555, CM1411099, COSV63714674, COSV63716448; called by muse, mutect2, varscan2
- VPS53 | c.99C>G p.S33R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52140357; called by muse, mutect2, varscan2
- ZNF556 | c.261T>A p.N87K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV56914964; called by muse, mutect2, varscan2
- NAA16 | c.1683G>A p.A561= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV65065327; called by muse, mutect2, varscan2
- LRRC69 | c.933+5956C>A | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87032G>A | Intron (SNP) | VAF 13/31 reads (42%) | catalogued as rs369034925; called by muse, mutect2, varscan2
- VEGFA | c.422+792G>A | Intron (SNP) | VAF 20/48 reads (42%) | catalogued as rs1307634204, COSV57878312; called by muse, mutect2, varscan2
